Gene-level copy-number profile of tumor specimen TCGA-43-7657-01A from TCGA case TCGA-43-7657, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 68.6 years (25,042 days).
Specimen TCGA-43-7657-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.9dcac346-5297-4dbc-aade-2b266d3d980b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-43-7657-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ae6f928c-7818-430d-849a-156c19ee7b80

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 1,743; copy number 2: 26,282; copy number 3: 19,040; copy number 4: 5,915; copy number 5: 3,466; copy number 6: 572; copy number 7: 466; copy number 8: 11; copy number 9: 853; copy number 14: 200; copy number 15: 7; copy number 16: 1,200; copy number 24: 48.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-43-7657-01A-31D-2121-01): tumor purity 0.44, ploidy 3.2, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,898,423–141,208,376, 4 genes: LRRC57P1, Y_RNA, RNU6-904P, RPS16P3.
- chr4:91,108,023–91,112,790, 1 gene: AC004054.1.
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.
- chr13:48,232,612–48,599,436, 8 genes (within-gene range 0–4): ITM2B, RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,814 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:129,430,947–198,222,513, 1,199 genes, copy number 14–16 (within-gene range 3–16) (broad region; genes not listed).
- chr4:51,843,000–55,798,731, 77 genes, copy number 14–24 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 9 (broad region; genes not listed).
- chr7:70,972–20,415,754, 325 genes, copy number 5 (broad region; genes not listed).
- chr7:21,900,899–159,233,377, 2,673 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr8:46,028,804–75,566,834, 457 genes, copy number 7 (broad region; genes not listed).
- chr8:112,222,928–113,436,939, 1 gene, copy number 6 (within-gene range 4–6): CSMD3.
- chr8:113,376,669–145,066,685, 515 genes, copy number 6 (broad region; genes not listed).
- chr17:42,940,575–50,768,730, 394 genes, copy number 5 (broad region; genes not listed).
- chr19:27,638,483–30,228,715, 63 genes, copy number 5–15 (broad region; genes not listed).
- chr19:30,850,975–30,872,507, 1 gene, copy number 5: AC011507.1.
- chr19:34,172,504–34,926,812, 35 genes, copy number 5: LSM14A, GARRE1, RPL29P33, AC010504.1, GPI, AC092073.1, PDCD2L, RN7SL154P, AC008747.1, UBA2, WTIP, RPS26P55, ZNF807P, SCGB1B2P, SCGB2B2, AC020910.4, AC020910.1, AC020910.2, AC020910.7, SCGB2B3P, AC020910.6, ZNF302, AC020910.5, ZNF181, ZNF599, AC020910.3, LINC01801, AC008555.1, AC008555.5, AC008555.2, AC008555.4, AC008555.3, LINC00904, LINC01838, ZNF30-AS1.
- chr19:35,040,506–40,777,490, 315 genes, copy number 9–16 (broad region; genes not listed).
- chr20:3,686,970–4,249,287, 22 genes, copy number 6 (within-gene range 4–6): SIGLEC1, HSPA12B, C20orf27, SPEF1, CENPB, CDC25B, LINC01730, AL109804.1, AP5S1, MAVS, PANK2-AS1, PANK2, MIR103A2, MIR103B2, AL031670.1, RNF24, FTLP3, RPL21P2, AL356414.1, SMOX, LINC01433, ADRA1D.
- chr20:24,297,585–24,666,616, 4 genes, copy number 5 (within-gene range 3–5): AL158090.1, GAPDHP53, SYNDIG1, AL157413.1.
- chr20:33,490,075–34,136,485, 23 genes, copy number 6: CBFA2T2, AL121906.2, NECAB3, C20orf144, ACTL10, ACTL10, AL121906.1, E2F1, PXMP4, AL050349.1, ZNF341, RPL31P2, ZNF341-AS1, CHMP4B, TPM3P2, PIGPP3, RALY-AS1, RALY, AL031668.1, MIR4755, EIF2S2, RPS2P1, AL031668.2.

Autosomal genes at a single copy (total copy number 1): 1,239. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
